Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHB, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHB-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 7,0 cm; no angio-invasion; no invasion of rete-testis;
no invasion of tunica albuginea; surgical margin spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3

Seminoma NOS 9061/3
Site: R Testis NOS C62.9
AD 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file f9117fd7-9e38-4221-98ed-7e76e73b41a2 (TCGA-2G-AAHB-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).